Somatic mutation profile of tumor specimen TCGA-MY-A913-01A (aliquot TCGA-MY-A913-01A-11D-A37N-09) from TCGA case TCGA-MY-A913, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIA; Tumor grade: G3; Age at diagnosis: 28.4 years (10,379 days).
Specimen TCGA-MY-A913-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5a8513d3-19b6-498e-a9b8-855a80a2565d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-MY-A913-10A (Blood Derived Normal), aliquot TCGA-MY-A913-10A-01D-A37N-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/841a696a-d501-4eb7-bab3-3d7e9a21547a

The open-access MAF lists 189 somatic variants for this specimen: 135 protein-altering or splice-affecting, 47 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 120, Silent 47, Nonsense Mutation 14, Intron 5, 5'UTR 1, Frame Shift Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA7 | c.188C>A p.S63* | Nonsense Mutation (SNP) | VAF 14/23 reads (61%) | catalogued as rs760419954, COSV99564903; called by muse, mutect2, varscan2
- ACAD10 | c.993G>T p.R331S | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.526); catalogued as COSV100563705; called by muse, mutect2, varscan2
- ACSM4 | c.629C>G p.S210C | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV101257011, COSV68068299; called by muse, mutect2, varscan2
- ADAP2 | c.328G>A p.E110K | Missense Mutation (SNP) | VAF 29/85 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV100437117; called by muse, mutect2, varscan2
- ADGRA2 | c.2977C>T p.L993F | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.897); catalogued as COSV99604650; called by muse, mutect2, varscan2
- ALDH5A1 | c.1600G>A p.G534S | Missense Mutation (SNP) | VAF 8/106 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.39); catalogued as rs925304801, COSV100708689; called by muse, mutect2
- ANO2 | c.1640C>A p.S547* (on ENST00000356134 / NM_001278597.3; = p.S551* on NM_001278596.3) | Nonsense Mutation (SNP) | VAF 15/52 reads (29%) | catalogued as COSV100499434; called by muse, mutect2, varscan2
- AP1B1 | c.724G>T p.E242* | Nonsense Mutation (SNP) | VAF 9/23 reads (39%) | catalogued as COSV100434290; called by muse, mutect2, varscan2
- ARHGEF11 | c.1000C>G p.Q334E | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100809544, COSV100809837; called by muse, mutect2, varscan2
- CACNA2D2 | c.807G>C p.K269N | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99816659, COSV99816691; called by muse, mutect2, varscan2
- CACNA2D2 | c.694G>C p.E232Q | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV99816694; called by muse, mutect2, varscan2
- CACUL1 | c.818C>G p.S273* | Nonsense Mutation (SNP) | VAF 13/50 reads (26%) | catalogued as COSV100432348; called by muse, mutect2, varscan2
- CAND1 | c.457G>A p.E153K | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV101598257; called by muse, mutect2, varscan2
- CBFA2T3 | c.1387G>A p.E463K | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.089); catalogued as rs769427504, COSV99240990; called by muse, mutect2, varscan2
- CCDC7 | c.225G>C p.K75N | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.974); catalogued as COSV53227495, COSV99511238; called by muse, mutect2, varscan2
- CCDC7 | c.4060G>C p.E1354Q | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.925); catalogued as COSV100177215; called by muse, varscan2
- CD177 | c.943C>G p.Q315E | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.039); catalogued as COSV100945761; called by muse, mutect2, varscan2
- CDH23 | c.7387C>G p.L2463V | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.68); catalogued as COSV99818309; called by muse, mutect2, varscan2
- CELSR3 | c.4644G>C p.Q1548H | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.01); catalogued as COSV51089101; called by muse, mutect2, varscan2
- CFAP45 | c.1361G>C p.R454T | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as COSV100928421; called by muse, mutect2, varscan2
- CLUH | c.3471G>C p.E1157D (on ENST00000435359; = p.E1196D on NM_015229.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.602); catalogued as COSV101425596; called by muse, mutect2, varscan2
- COPZ1 | c.133G>C p.E45Q | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV100017596; called by muse, mutect2, varscan2
- CRHR1 | c.286C>T p.R96C | Missense Mutation (SNP) | VAF 35/85 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as rs1308251615, COSV53283635, COSV53286649; called by muse, mutect2, varscan2
- DENND2A | c.1150G>A p.E384K | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV99325401; called by muse, mutect2, varscan2
- DENND4A | c.5353G>A p.E1785K | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.214); catalogued as COSV101475242; called by muse, mutect2, varscan2
- DNAJC5 | c.484G>C p.D162H | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.838); catalogued as COSV100694115; called by muse, varscan2
- DPF1 | c.822C>G p.I274M | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV100831394, COSV62794060; called by muse, mutect2, varscan2
- DPH5 | c.107C>G p.S36* | Nonsense Mutation (SNP) | VAF 5/35 reads (14%) | catalogued as COSV100587333; called by muse, mutect2, varscan2
- DPP4 | c.2212G>A p.E738K | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.08); catalogued as rs751368178, COSV100858640; called by muse, mutect2, varscan2
- DST | c.18162C>G p.F6054L (on ENST00000361203 / NM_001374722.1; = p.F3751L on NM_015548.5) | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV99749717; called by muse, mutect2, varscan2
- DYM | c.113C>G p.S38* | Nonsense Mutation (SNP) | VAF 19/48 reads (40%) | catalogued as COSV99492381; called by muse, mutect2, varscan2
- EIF1AX | c.9G>C p.K3N | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.378); catalogued as COSV65451736; called by muse, mutect2, varscan2
- ENPP5 | c.1039G>C p.D347H | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.289); catalogued as COSV100040185; called by muse, mutect2, varscan2
- EXOC4 | c.476C>T p.S159L | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.115); catalogued as rs746175040, COSV54102771; called by muse, mutect2, varscan2
- GABBR1 | c.1018C>T p.R340C | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV63542745; called by muse, mutect2, varscan2
- GOLGB1 | c.762G>C p.L254F | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100510209; called by muse, mutect2, varscan2
- GPS1 | c.676G>C p.E226Q | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.52); catalogued as COSV57650206; called by muse, mutect2, varscan2
- GRAMD4 | c.346C>T p.R116C | Missense Mutation (SNP) | VAF 10/17 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.61); catalogued as rs1245587159, COSV100730261; called by muse, mutect2, varscan2
- GTF2IRD2 | c.1780G>A p.E594K | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as COSV100736379; called by muse, mutect2, varscan2
- HDAC5 | c.3061G>A p.A1021T | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.683); catalogued as COSV99291120; called by muse, mutect2, varscan2
- HECTD4 | c.2107G>A p.D703N | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as COSV100295751; called by muse, mutect2, varscan2
- HECW2 | c.273G>C p.W91C | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53656841; called by muse, mutect2, varscan2
- HSD11B1 | c.34C>A p.L12M | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.62); catalogued as COSV99807847; called by muse, mutect2, varscan2
- IGLON5 | c.550G>T p.D184Y | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.903); catalogued as COSV99570403; called by muse, mutect2, varscan2
- KCNJ13 | c.1045G>T p.D349Y | Missense Mutation (SNP) | VAF 15/29 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99289165; called by muse, mutect2, varscan2
- KDM6B | c.1336C>T p.R446W | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.897); catalogued as rs375353410; called by muse, mutect2, varscan2
- KLF10 | c.1253G>A p.R418K | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99574560; called by muse, mutect2
- KLHL11 | c.1126G>A p.E376K | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.099); catalogued as COSV100044135; called by muse, mutect2, varscan2
- KNTC1 | c.424G>C p.E142Q | Missense Mutation (SNP) | VAF 33/99 reads (33%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.738); catalogued as COSV100337811; called by muse, mutect2, varscan2
- KRT4 | c.1475C>A p.S492Y | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0.336); catalogued as COSV99542523; called by muse, mutect2, varscan2
- L1TD1 | c.358G>A p.E120K | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as COSV100776519; called by muse, mutect2, varscan2
- LILRB3 | c.1639G>A p.D547N (on ENST00000346401; = p.D535N on NM_006864.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/90 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0.216); catalogued as rs775829597, COSV54430721; called by muse, varscan2
- LIN7A | c.197G>A p.R66Q | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs201514763, COSV99691594; called by muse, mutect2, varscan2
- LMO7 | c.2239G>C p.E747Q (on ENST00000357063; = p.E428Q on NM_005358.5) | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100412225, COSV58542021; called by muse, mutect2, varscan2
- LMX1B | c.463G>A p.E155K | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.923); catalogued as rs776839118, COSV62741637; called by muse, mutect2, varscan2
- LPCAT4 | c.967G>C p.E323Q | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV59217593; called by muse, mutect2, varscan2
- MANEA | c.742C>T p.H248Y | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV62589433; called by muse, mutect2
- MAP4K2 | c.738C>A p.F246L | Missense Mutation (SNP) | VAF 22/118 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as COSV53648500, COSV99580102; called by muse, mutect2, varscan2
- MAPK7 | c.160G>A p.E54K | Missense Mutation (SNP) | VAF 30/70 reads (43%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.845); catalogued as rs1364671960, COSV100218738; called by muse, mutect2, varscan2
- MCM10 | c.404T>C p.V135A | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as COSV101097844, COSV66332977; called by muse, mutect2, varscan2
- MDC1 | c.964C>T p.Q322* | Nonsense Mutation (SNP) | VAF 8/37 reads (22%) | catalogued as COSV64523779, COSV64525512; called by muse, mutect2, varscan2
- METTL5 | c.241G>C p.D81H | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53627781; called by muse, mutect2, varscan2
- MIA | c.328G>A p.E110K | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99648117; called by muse, mutect2, varscan2
- MOV10L1 | c.1641G>T p.M547I | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV53177988, COSV99432310; called by muse, mutect2, varscan2
- MSS51 | c.151G>C p.D51H | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); catalogued as COSV100200062; called by muse, mutect2, varscan2
- MUC16 | c.5336C>G p.S1779* | Nonsense Mutation (SNP) | VAF 8/56 reads (14%) | catalogued as COSV67482708, COSV67496033; called by muse, mutect2, varscan2
- MUC16 | c.4690C>G p.P1564A | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.908); catalogued as COSV101197460; called by muse, mutect2, varscan2
- MUC16 | c.4235C>G p.S1412* | Nonsense Mutation (SNP) | VAF 23/93 reads (25%) | catalogued as COSV101197461; called by muse, mutect2, varscan2
- MUC16 | c.3902C>T p.S1301F | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.635); catalogued as COSV101197466; called by muse, mutect2, varscan2
- MUC16 | c.3470C>T p.S1157F | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.955); catalogued as rs560462497, COSV101197468, COSV101197907; called by muse, mutect2, varscan2
- MUC16 | c.3380C>G p.S1127* | Nonsense Mutation (SNP) | VAF 10/38 reads (26%) | catalogued as COSV101197470, COSV67455366; called by muse, mutect2, varscan2
- MUC16 | c.2639C>T p.S880F | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.955); catalogued as COSV101197473; called by muse, varscan2
- MUC17 | c.8225G>C p.R2742P | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs779359409, COSV60289624, COSV60307815; called by muse, mutect2, varscan2
- NAV3 | c.6625G>A p.D2209N (on ENST00000397909 / NM_001024383.2; = p.D2187N on NM_014903.6) | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.505); catalogued as COSV99885995, COSV99886692; called by muse, mutect2, varscan2
- NF1 | c.6745C>G p.L2249V (on ENST00000358273 / NM_001042492.3; = p.L2228V on NM_000267.3) | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.418); catalogued as COSV100645809, COSV62194159; called by muse, mutect2, varscan2
- NIPSNAP3B | c.364G>C p.D122H | Missense Mutation (SNP) | VAF 35/74 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.06); catalogued as COSV101044387, COSV66106711; called by muse, mutect2, varscan2
- NOS1 | c.940G>A p.E314K | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV57614838; called by muse, mutect2, varscan2
- NUMBL | c.448G>C p.D150H | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53285175; called by muse, mutect2, varscan2
- OR2A5 | c.80C>G p.S27C | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV101278629, COSV68739139; called by muse, mutect2, varscan2
- ORAI2 | c.250G>C p.E84Q | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.099); catalogued as COSV100709817; called by muse, mutect2, varscan2
- P2RY4 | c.449G>A p.R150H | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0.021); catalogued as rs750283070, COSV100996949; called by mutect2, varscan2
- PABPC1L | c.1546G>A p.A516T | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as COSV99407406; called by muse, mutect2, varscan2
- PATE2 | c.256G>A p.D86N | Missense Mutation (SNP) | VAF 17/26 reads (65%) | SIFT tolerated (0.2); PolyPhen benign (0.03); catalogued as COSV100653418; called by muse, mutect2, varscan2
- PAXIP1 | c.1962G>C p.E654D | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.652); catalogued as COSV101249219; called by muse, mutect2, varscan2
- PCCA | c.1544A>C p.H515P | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.535); catalogued as COSV100886416; called by muse, mutect2, varscan2
- PDS5A | c.1981G>C p.E661Q | Missense Mutation (SNP) | VAF 26/51 reads (51%) | SIFT tolerated (0.22); PolyPhen benign (0.062); catalogued as COSV100337081; called by muse, mutect2, varscan2
- PDS5B | c.3553G>A p.E1185K | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.858); catalogued as COSV100220334; called by muse, mutect2, varscan2
- PER3 | c.2136G>C p.R712S | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (0.21); PolyPhen benign (0.095); catalogued as COSV100728181; called by muse, mutect2, varscan2
- PIK3C2A | c.1696C>G p.Q566E | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT tolerated (0.77); PolyPhen benign (0.014); catalogued as COSV99790079; called by muse, mutect2, varscan2
- PTCH2 | c.3492C>G p.I1164M | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as COSV100807934; called by muse, mutect2, varscan2
- PTPRD | c.2993C>T p.T998M | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.652); catalogued as rs547908736, COSV61981604; called by muse, mutect2, varscan2
- RAPGEF6 | c.2536C>G p.Q846E | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.593); catalogued as COSV57239963; called by muse, mutect2, varscan2
- RFC2 | c.722C>G p.S241* (on ENST00000055077 / NM_181471.3; = p.S207* on NM_002914.4) | Nonsense Mutation (SNP) | VAF 6/31 reads (19%) | catalogued as COSV99277661; called by muse, mutect2, varscan2
- RNF168 | c.814G>C p.E272Q | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT deleterious (0); PolyPhen benign (0.441); catalogued as rs1446897289, COSV100534807; called by muse, mutect2, varscan2
- RNF17 | c.3152C>A p.S1051* | Nonsense Mutation (SNP) | VAF 14/22 reads (64%) | catalogued as COSV55036479; called by muse, mutect2, varscan2
- RP1L1 | c.2434C>T p.R812W | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs761665772, COSV101222851; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RPL41 | c.53G>A p.R18K | Missense Mutation (SNP) | VAF 20/64 reads (31%) | catalogued as COSV99230335; called by muse, mutect2, varscan2
- SARDH | c.722G>A p.R241H | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT tolerated (0.17); PolyPhen benign (0.009); catalogued as rs755017202, COSV53836478; called by muse, mutect2, varscan2
- SCN11A | c.4843G>C p.E1615Q | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.374); catalogued as COSV100180664, COSV56566393; called by muse, mutect2, varscan2
- SERPINF1 | c.668C>G p.S223C | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.797); catalogued as COSV54616968, COSV99628633; called by muse, mutect2, varscan2
- SHISAL2A | c.376G>A p.E126K | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.533); catalogued as COSV101284202; called by muse, mutect2, varscan2
- SIN3A | c.2072C>T p.A691V | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.896); catalogued as COSV100845005; called by muse, mutect2
- SIX5 | c.1789G>C p.E597Q | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.188); catalogued as COSV99352633; called by muse, mutect2, varscan2
- SLC13A1 | c.159G>T p.L53F | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV52012308, COSV99520240; called by muse, mutect2, varscan2
- SLC36A3 | c.793G>C p.E265Q | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100077271, COSV58858286; called by muse, mutect2, varscan2
- SLC39A7 | c.256G>C p.E86Q | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0.05); PolyPhen benign (0.073); catalogued as COSV100807540; called by muse, mutect2, varscan2
- SLC44A2 | c.987C>G p.I329M | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.951); catalogued as COSV100212904; called by muse, mutect2, varscan2
- SLC7A6OS | c.188C>T p.S63F | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1338758377, COSV99862254; called by muse, mutect2, varscan2
- SMG1 | c.7594C>A p.L2532M | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV101244943; called by muse, mutect2, varscan2
- SOX11 | c.232G>A p.E78K | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV58988296; called by muse, mutect2, varscan2
- SPATA1 | c.1181G>C p.R394T | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99759577; called by muse, mutect2, varscan2
- SPATA16 | c.640G>C p.E214Q | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as COSV100650782, COSV63531143; called by muse, mutect2, varscan2
- SRGAP2 | c.2425G>C p.E809Q (on ENST00000624873 / NM_001170637.4; = p.E810Q on NM_015326.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.597); catalogued as COSV99832230; called by muse, mutect2
- STAT1 | c.1108G>C p.E370Q | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.2); PolyPhen benign (0.015); catalogued as COSV100738389; called by muse, mutect2, varscan2
- TOX | c.611C>G p.S204* | Nonsense Mutation (SNP) | VAF 18/35 reads (51%) | catalogued as COSV100812534; called by muse, mutect2, varscan2
- TP53BP2 | c.724G>A p.E242K (on ENST00000343537 / NM_001031685.3; = p.E113K on NM_005426.2) | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100636485; called by muse, mutect2, varscan2
- TRABD2A | c.1259G>A p.R420Q (on ENST00000409520 / NM_001277053.2; = p.R371Q on NM_001080824.3) | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs757790660, COSV52851337; called by mutect2, varscan2
- TSPAN14 | c.720C>A p.F240L | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.082); catalogued as COSV99627738; called by muse, mutect2, varscan2
- TTC38 | c.1254C>G p.F418L | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.904); catalogued as COSV101123843, COSV101123908; called by muse, mutect2, varscan2
- TTLL3 | c.2617G>A p.A873T | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.003); catalogued as rs540084396, COSV100047068; called by muse, mutect2, varscan2
- TTLL5 | c.978C>G p.I326M | Missense Mutation (SNP) | VAF 32/65 reads (49%) | SIFT tolerated (0.06); PolyPhen benign (0.243); catalogued as COSV100088564; called by muse, mutect2, varscan2
- TTN | c.82871G>A p.G27624E (on ENST00000591111; = p.G20200E on NM_003319.4) | Missense Mutation (SNP) | VAF 7/20 reads (35%) | PolyPhen probably damaging (1); catalogued as COSV100589900, COSV60180991; called by muse, mutect2, varscan2
- TTN | c.16502C>T p.S5501L (on ENST00000591111; = p.S4574L on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/45 reads (18%) | PolyPhen benign (0.173); catalogued as rs749007462, COSV60159251; called by muse, mutect2, varscan2
- TUBB2A | c.1201G>A p.E401K | Missense Mutation (SNP) | VAF 7/76 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV100373730; called by muse, mutect2, varscan2
- USP16 | c.251G>C p.R84T | Missense Mutation (SNP) | VAF 19/36 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100537761; called by muse, varscan2
- USP34 | c.5749G>A p.E1917K | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.72); catalogued as COSV101276532; called by muse, mutect2, varscan2
- VPS25 | c.34C>G p.R12G | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV99519231; called by muse, mutect2, varscan2
- ZNF280B | c.1348C>T p.H450Y | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.596); catalogued as COSV64529786; called by muse, mutect2, varscan2
- ZNF296 | c.558G>C p.Q186H | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV99673402; called by muse, mutect2, varscan2
- ZNF521 | c.694C>T p.Q232* | Nonsense Mutation (SNP) | VAF 15/37 reads (41%) | catalogued as COSV100831305; called by muse, mutect2, varscan2
- ZNF583 | c.126G>T p.L42F | Missense Mutation (SNP) | VAF 4/73 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV99381912; called by muse, mutect2
- ZNF875 | c.1643C>T p.S548L | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.411); catalogued as COSV100182989; called by muse, mutect2, varscan2
- CWC25 | c.1018G>C p.E340Q | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TUBGCP5 | c.2833G>C p.E945Q | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.124); called by mutect2, varscan2
- WFIKKN2 | c.299del p.K100Rfs*74 | Frame Shift Del (DEL) | VAF 9/40 reads (23%) | called by pindel, varscan2
- ADRA2B | c.444C>A p.L148= | Silent (SNP) | VAF 10/27 reads (37%) | catalogued as COSV101337336; called by muse, mutect2, varscan2
- APOOL | c.12C>T p.I4= | Silent (SNP) | VAF 25/53 reads (47%) | catalogued as rs764151366, COSV100920784; called by muse, mutect2, varscan2
- ARHGAP35 | c.3285G>A p.V1095= | Silent (SNP) | VAF 14/34 reads (41%) | catalogued as COSV101350627; called by muse, mutect2, varscan2
- ATRAID | c.814C>T p.L272= (on ENST00000611786; = p.L159= on NM_016085.5) | Silent (SNP) | VAF 6/25 reads (24%) | catalogued as COSV99254257, COSV99254977; called by muse, mutect2, varscan2
- BOC | c.120C>G p.V40= | Silent (SNP) | VAF 19/40 reads (48%) | catalogued as COSV99847827; called by muse, mutect2, varscan2
- CBLIF | c.684C>T p.L228= | Silent (SNP) | VAF 25/52 reads (48%) | catalogued as rs373712844; called by muse, mutect2, varscan2
- CHRM3 | c.1479C>T p.L493= | Silent (SNP) | VAF 6/31 reads (19%) | catalogued as COSV55080395; called by muse, mutect2, varscan2
- DDX49 | c.297G>A p.L99= | Silent (SNP) | VAF 21/77 reads (27%) | catalogued as COSV99447042; called by muse, mutect2, varscan2
- DLG5 | c.879C>T p.N293= | Silent (SNP) | VAF 13/27 reads (48%) | catalogued as rs767909516, COSV64948565; called by muse, mutect2, varscan2
- DOCK6 | c.5973G>A p.L1991= | Silent (SNP) | VAF 5/36 reads (14%) | catalogued as COSV99624438; called by muse, mutect2
- DPYD | c.1569C>A p.L523= | Silent (SNP) | VAF 7/36 reads (19%) | catalogued as COSV64609935; called by muse, mutect2, varscan2
- ELP1 | c.1389G>A p.V463= | Silent (SNP) | VAF 14/62 reads (23%) | catalogued as COSV101010273, COSV65899569; called by muse, mutect2, varscan2
- EP400 | c.6795G>A p.R2265= | Silent (SNP) | VAF 5/25 reads (20%) | catalogued as COSV100200116; called by muse, mutect2, varscan2
- EXD3 | c.696G>C p.L232= | Silent (SNP) | VAF 11/32 reads (34%) | catalogued as COSV100573330; called by muse, mutect2, varscan2
- FAM189B | c.465G>A p.L155= | Silent (SNP) | VAF 21/51 reads (41%) | catalogued as rs747731053, COSV100226560; called by muse, mutect2, varscan2
- FARSA | c.1080G>A p.E360= | Silent (SNP) | VAF 15/96 reads (16%) | catalogued as COSV100108593; called by muse, mutect2, varscan2
- GALNT3 | c.1713G>A p.L571= | Silent (SNP) | VAF 21/58 reads (36%) | catalogued as COSV67062775; called by muse, mutect2, varscan2
- GOLGB1 | c.5571G>A p.Q1857= | Silent (SNP) | VAF 10/26 reads (38%) | catalogued as COSV100510208; called by muse, mutect2, varscan2
- H3-3B | c.81G>A p.R27= | Silent (SNP) | VAF 26/79 reads (33%) | catalogued as rs144205696; called by muse, mutect2, varscan2
- HEATR4 | c.2151C>G p.L717= | Silent (SNP) | VAF 20/34 reads (59%) | catalogued as COSV100620116; called by muse, mutect2, varscan2
- INTS4 | c.219C>G p.V73= | Silent (SNP) | VAF 12/50 reads (24%) | catalogued as COSV101417106; called by muse, mutect2, varscan2
- LHX4 | c.370C>T p.L124= | Silent (SNP) | VAF 14/48 reads (29%) | catalogued as COSV99761080; called by muse, mutect2, varscan2
- MBD1 | c.186C>T p.F62= | Silent (SNP) | VAF 23/54 reads (43%) | catalogued as rs772372557, COSV54007559; called by muse, mutect2, varscan2
- MPDZ | c.4645C>T p.L1549= | Silent (SNP) | VAF 9/31 reads (29%) | catalogued as rs369732746, COSV100056004; called by muse, mutect2, varscan2
- MTX1 | c.852C>T p.L284= | Silent (SNP) | VAF 16/35 reads (46%) | catalogued as COSV100003191; called by muse, mutect2, varscan2
- MUC16 | c.4041C>G p.L1347= | Silent (SNP) | VAF 18/115 reads (16%) | catalogued as COSV101197464; called by muse, mutect2, varscan2
- MUC16 | c.2514C>T p.L838= | Silent (SNP) | VAF 12/84 reads (14%) | catalogued as COSV101197475, COSV67464116; called by muse, varscan2
- MUC16 | c.1773C>T p.I591= | Silent (SNP) | VAF 12/55 reads (22%) | catalogued as rs371667879, COSV67457500; called by muse, mutect2, varscan2
- MYO7B | c.2916C>G p.T972= | Silent (SNP) | VAF 22/75 reads (29%) | catalogued as COSV101267814, COSV67347661; called by muse, mutect2, varscan2
- NPPA | c.291C>T p.L97= | Silent (SNP) | VAF 7/22 reads (32%) | catalogued as rs941079012, COSV100411466; called by muse, mutect2, varscan2
- NRBP1 | c.474G>C p.L158= | Silent (SNP) | VAF 19/51 reads (37%) | catalogued as rs929423472, COSV99274701, COSV99275294; called by muse, mutect2, varscan2
- NSF | c.1260C>T p.L420= | Silent (SNP) | VAF 21/73 reads (29%) | catalogued as COSV99833611; called by mutect2, varscan2
- OR4C13 | c.549C>T p.I183= | Silent (SNP) | VAF 5/38 reads (13%) | catalogued as COSV101634129, COSV101634132; called by muse, mutect2, varscan2
- PCIF1 | c.1875C>T p.I625= | Silent (SNP) | VAF 10/24 reads (42%) | catalogued as COSV100532540; called by muse, mutect2, varscan2
- PDCD6IP | c.72C>T p.F24= | Silent (SNP) | VAF 26/55 reads (47%) | catalogued as COSV100218434; called by muse, mutect2, varscan2
- PNPLA7 | c.153G>A p.R51= | Silent (SNP) | VAF 31/71 reads (44%) | catalogued as COSV99479887; called by muse, mutect2, varscan2
- PSMC1 | c.1212G>C p.L404= | Silent (SNP) | VAF 14/72 reads (19%) | catalogued as COSV99728092; called by muse, mutect2, varscan2
- PTPN13 | c.3450G>A p.V1150= (on ENST00000411767 / NM_080683.3; = p.V1131= on NM_006264.3) | Silent (SNP) | VAF 15/22 reads (68%) | catalogued as COSV100363864; called by muse, mutect2, varscan2
- RNF17 | c.3234G>T p.V1078= | Silent (SNP) | VAF 19/34 reads (56%) | catalogued as COSV99691882; called by muse, mutect2, varscan2
- SLC24A2 | c.1611G>C p.L537= | Silent (SNP) | VAF 11/32 reads (34%) | catalogued as COSV99645569; called by muse, mutect2, varscan2
- TIMM29 | c.612G>A p.L204= | Silent (SNP) | VAF 27/119 reads (23%) | catalogued as COSV99449745; called by muse, mutect2, varscan2
- TMC3 | c.1570C>T p.L524= | Silent (SNP) | VAF 11/25 reads (44%) | catalogued as COSV100845818, COSV100845837; called by muse, mutect2, varscan2
- TMTC4 | c.1803G>A p.V601= (on ENST00000376234 / NM_001350577.2; = p.V620= on NM_032813.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 12/35 reads (34%) | catalogued as COSV100168388; called by muse, mutect2, varscan2
- TRAF2 | c.1026C>T p.V342= | Silent (SNP) | VAF 7/28 reads (25%) | catalogued as rs200115576, COSV56036051; called by muse, mutect2, varscan2
- XKR6 | c.894G>A p.E298= | Silent (SNP) | VAF 14/29 reads (48%) | catalogued as COSV100440125; called by muse, mutect2, varscan2
- ZNF324 | c.585G>A p.Q195= | Silent (SNP) | VAF 7/32 reads (22%) | catalogued as COSV99543052; called by muse, mutect2, varscan2
- ZSCAN20 | c.3090C>T p.F1030= | Silent (SNP) | VAF 10/27 reads (37%) | catalogued as COSV63684630; called by muse, mutect2, varscan2
- C9orf85 | c.323+1133G>C | Intron (SNP) | VAF 8/37 reads (22%) | catalogued as COSV100594932; called by muse, varscan2
- C9orf85 | c.323+1218G>A | Intron (SNP) | VAF 7/18 reads (39%) | catalogued as COSV100594933; called by muse, varscan2
- CA6 | c.259+1997C>T | Intron (SNP) | VAF 14/38 reads (37%) | catalogued as COSV101077296, COSV66262833; called by muse, mutect2, varscan2
- IGKV1OR22-5 | n.201A>T | RNA (SNP) | VAF 30/138 reads (22%) | called by muse, mutect2, varscan2
- KDM5B | c.-1G>A | 5'UTR (SNP) | VAF 14/32 reads (44%) | catalogued as COSV99349901; called by muse, mutect2
- TTN | c.10360+3541C>A | Intron (SNP) | VAF 12/43 reads (28%) | catalogued as COSV100589904, COSV100589986; called by muse, mutect2, varscan2
- VGLL4 | c.255-17278G>A | Intron (SNP) | VAF 5/27 reads (19%) | catalogued as COSV99809052; called by muse, mutect2, varscan2
